Gene-level copy-number profile of tumor specimen C3L-02163-01 from CPTAC case C3L-02163, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 57.5 years (21,020 days).
Specimen C3L-02163-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2332f9fb-1473-4e60-94b1-ed22a2b32462.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02163-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/a97cd693-c117-4134-aec9-865d24e645a6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 534; copy number 1: 1,181; copy number 2: 22,226; copy number 3: 22,023; copy number 4: 9,946; copy number 5: 1,552; copy number 6: 191; copy number 7: 526; copy number 8: 156; copy number 9: 560.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes (within-gene range 0–3): RNU6-904P, RPS16P3.
- chr9:8,700,595–8,797,194, 3 genes (within-gene range 0–1): AL583805.2, AL583805.1, RNU7-185P.
- chr9:10,532,145–11,013,096, 7 genes (within-gene range 0–1): AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1.
- chr15:21,951,242–21,951,323, 1 gene: MIR5701-3.
- chr15:22,056,709–22,057,638, 1 gene (within-gene range 0–1): OR4H6P.
- chr17:18,426,861–18,551,705, 11 genes (within-gene range 0–3): KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,242 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:150,541,998–198,123,232, 824 genes, copy number 7–9 (broad region; genes not listed).
- chr5:18,547,312–22,853,344, 31 genes, copy number 7: RN7SL58P, LINC02100, UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1.
- chr5:29,600,676–30,365,684, 8 genes, copy number 7: UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1, HPRT1P2, AC114300.1.
- chr5:41,730,065–45,895,970, 68 genes, copy number 7–8 (broad region; genes not listed).
- chr22:20,198,729–24,270,134, 311 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,098. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
